Gene-level copy-number profile of tumor specimen TCGA-AA-A01G-01A from TCGA case TCGA-AA-A01G, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Cecum; AJCC pathologic stage: Stage IIA; Age at diagnosis: 63.3 years (23,133 days).
Specimen TCGA-AA-A01G-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.e0a8075d-3f76-441f-bda9-4585033916ce.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AA-A01G-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 397 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/70a571e0-7dc0-4088-ac6a-ed21dea4a282

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 9; copy number 1: 5; copy number 2: 4,155; copy number 3: 959; copy number 4: 39,437; copy number 5: 3,794; copy number 6: 6,043; copy number 7: 2,593; copy number 8: 2,200; copy number 9: 1,011; copy number 10: 17; copy number 11: 1; copy number 12: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-AA-A01G-01): tumor purity 0.52, ploidy 4.44, whole-genome doublings 1 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 9 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:9,480,608–9,576,275, 2 genes: AC092821.1, AC092821.2.
- chr16:6,573,767–6,874,005, 5 genes: AC007223.1, AC007012.2, AC007012.1, RNU7-99P, RNU6-457P.
- chr17:41,265,339–41,271,835, 2 genes: KRTAP9-6, KRTAP9-11P.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,031 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:67,440,998–67,442,559, 1 gene, copy number 11: LINC02420.
- chr13:19,026,001–19,032,626, 2 genes, copy number 12: GTF2IP3, AL137001.1.
- chr17:21,614,487–22,332,410, 14 genes, copy number 10 (within-gene range 2–10): AC233702.1, AC233702.4, AC233702.9, KCNJ18, AC243725.1, ABBA01006766.1, NCOR1P2, UBBP4, FTLP13, LINC02002, AC138761.1, AC138761.2, FAM27E5, AC087575.1.
- chr20:15,552,157–21,535,665, 119 genes, copy number 9 (within-gene range 8–9) (broad region; genes not listed).
- chr20:22,220,554–39,933,239, 437 genes, copy number 9–10 (broad region; genes not listed).
- chr20:40,685,848–53,495,330, 310 genes, copy number 9 (within-gene range 8–9) (broad region; genes not listed).
- chr20:55,408,898–55,684,915, 1 gene, copy number 9 (within-gene range 8–9): LINC01440.
- chr20:55,504,906–55,744,938, 2 genes, copy number 9: AL160413.1, AL109829.1.
- chr20:56,248,732–62,551,526, 144 genes, copy number 9 (broad region; genes not listed).
- chr20:62,554,306–62,554,376, 1 gene, copy number 9: MIR1-1.

Autosomal genes at a single copy (total copy number 1): 5. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
